Somatic mutation profile of tumor specimen ALCH-AEYL-TTP1-A (aliquot ALCH-AEYL-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEYL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.0 years (17,531 days).
Specimen ALCH-AEYL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ac860a5-31ec-401a-b3b0-a5aaa9d39ffa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEYL-NB1-A (Blood Derived Normal), aliquot ALCH-AEYL-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06b135d0-dd6e-47a7-aa98-b50f9b8f3a9b

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Frame Shift Del 3, RNA 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 175/719 reads (24%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- BPI | c.1157T>A p.L386H (on ENST00000262865; = p.L382H on NM_001725.3) | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780414569; called by muse, mutect2, varscan2
- GALNT14 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100204024; called by muse, mutect2
- SLCO1B1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300186922; called by muse, mutect2, varscan2
- STEAP3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs754445970, COSV61530464; called by mutect2, varscan2
- ZNF518B | c.2621A>G p.N874S | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148372722; called by muse, mutect2
- ATP2B4 | c.2422_2423del p.D808Cfs*13 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- EPB41 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 42/497 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- LARGE2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LRFN1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MTF2 | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- POM121L12 | c.653_668del p.K218Mfs*14 | Frame Shift Del (DEL) | VAF 14/158 reads (9%) | called by mutect2, pindel
- SPTA1 | c.5822A>G p.E1941G | Missense Mutation (SNP) | VAF 17/546 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TGFB1I1 | c.1376T>A p.L459H (on ENST00000394863 / NM_001042454.3; = p.L442H on NM_015927.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF585B | c.273del p.R91Sfs*59 | Frame Shift Del (DEL) | VAF 47/401 reads (12%) | called by mutect2, varscan2
- ATRX | c.1032C>T p.S344= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as rs143491422, COSV64879104; ClinVar: benign; called by muse, mutect2
- COL16A1 | c.3870G>A p.P1290= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as rs747943743, COSV104375291; called by muse, mutect2, varscan2
- FGD2 | c.522C>T p.D174= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs756298412; called by muse, mutect2, varscan2
- GOLGA8J | c.1674T>A p.G558= | Silent (SNP) | VAF 20/413 reads (5%) | called by muse, mutect2
- HYDIN | c.14055G>A p.K4685= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as rs533531507; called by muse, mutect2
- PAPPA2 | c.1000C>A p.R334= | Silent (SNP) | VAF 55/312 reads (18%) | catalogued as COSV62789004; called by muse, mutect2, varscan2
- PRRC2B | c.1947G>A p.V649= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs377610763; called by muse, mutect2, varscan2
- MIR9-1HG | n.100C>T | RNA (SNP) | VAF 34/287 reads (12%) | catalogued as rs1366765131, COSV100023977, COSV59485795; called by muse, mutect2, varscan2
- SNAI2 | c.*4A>C | 3'UTR (SNP) | VAF 14/376 reads (4%) | catalogued as rs1368442934; called by muse, mutect2
